CCDI case PBBITF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4852c632-1748-4941-8a6d-cc7c6dc36e17

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Atypical choroid plexus papilloma: ICD-O-3 morphology code: 9390/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 0.8 years (296 days).

Biospecimens (3 samples)
- Sample 0D9DQL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9DQN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0D9DQO: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
